Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A3L1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A3L1-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

KMT 12/19/11

Diagnosis:

A: Paratubal cyst, excision

- Benign paratubal cyst

- Nodule of mature adipose tissue consistent with appendix epiploica

B: Cervix and uterus, radical hysterectomy

Histologic type: Squamous cell carcinoma, non-keratinizing, with marked

acute and chronic inflammatory infiltrate

ICD-O-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9

Histologic grade: Poorly differentiated

12/19/11

Tumor size: 3.9 cm x 3.3 cm x 0.6 cm

Tumor site:

- Circumferential cervical involvement except 0.6 cm area on posterior cervical

lip

- Tumor involves the anterior lower uterine segment

Extent of invasion: Stromal invasion is 6 mm in 9 mm stromal wall thickness

(at thinnest portion of cervical canal), or 67%

Parametrial involvement: Absent

Vaginal margin and distance: Vaginal cuff margin negative, 7 mm

Tumor extends to 2 mm from right anterolateral, bladder flap, margin

Lymphovascular space invasion: None identified

Perineural invasion: None identified

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 22

Other pathologic findings:

[page 2 of 4]
Endometrium

- Secretory endometrium

Myometrium

- No specific pathologic abnormalities

AJCC Pathologic Stage: pT2a1 pN0

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

C: Left BLN, lymph node dissection

- Six lymph nodes, negative for metastatic carcinoma (0/6)

D: Right BLN, lymph node dissection

- Sixteen lymph nodes, negative for metastatic carcinoma (0/16)

Clinical History:

year-old female with cervical carcinoma.

Gross Description:

Specimen A is labeled "left paratubal cyst" and consists of a single yellow/tan

soft tissue fragment measuring 1.1 x 0.6 x 0.5 cm. The external surface is

yellow/tan, smooth, unremarkable. Cut section is smooth, with thin walled

approximately 0.05 cm in diameter. Consists of serous yellow fluid. The

specimen is serially sectioned and submitted entirely in block A1,

Specimen B is received in one appropriately labeled container:

Specimen fixation: Formalin

Specimen type: Radical hysterectomy

Adnexa: Not present

Weight: 142.3 grams

[page 3 of 4]
Shape: Pear- shaped

Dimensions:

Height: 9.9 cm

Anterior to posterior width: 5.9 cm

Breadth at fundus: 6 cm

Serosa: Brown/tan, smooth and unremarkable

Orientation: Inking: anterior/blue, posterior/black

Cervix:

Tumor size: 3.9 cm superior to inferior, 3.3 cm in circumference

Tumor site: The tumor is circumferential except for a 0.6 cm area on the posterior cervical lip. The tumor spans the external os, extending

to the lower uterine segment. The tumor is brown/tan, somewhat nodular, with

pushing heaped up edges. On cut section the tumor has a thickness of 0.6 cm.

Ectocervical margin is 0.5 cm and the tumor abuts the right lateral wall soft tissue margin.

Endometrium:

Length of endometrial cavity: 4 cm

Width: 3.1 cm

Endometrial surface: Lush, unremarkable

Other findings: None

Myometrium:

Thickness of the wall: 2.6 cm

Other findings: None

Other organs present: None

Vagina: A small vaginal cuff is identified.

Urinary bladder: N/A

Rectum: N/A

Digital picture: Not taken.

Block Summary:

B1 - Perpendicular epithelial margin, anterior side

B2 - Anterior epithelial margin, en face

[page 4 of 4]
B3 - Posterior epithelial margin, en face
B4 - Perpendicular sections showing the closest approach of tumor to soft tissue
B5-B6 - Sections from the anterior cervix and lower uterine segment
B7-B8 - Section from the posterior cervix and lower uterine segment
B9 - Representative sections of the tumor
B10 - Anterior endomyometrium, mid corpus
B11 - Posterior endomyometrium, mid corpus
B12-B16 - Serial sections of the right parametrium from proximal to distal
B17-B20 - Serial sections of the left parametrium from proximal to distal

Specimen C is labeled "left BLN" and is a single fragment of yellow/tan fibrofatty tissue measuring 5.6 x 3.2 x 1.1 cm in aggregate. Three lymph node candidates are identified ranging in size from 0.5 cm to 2.5 x 1.1 x 0.5 cm.

Block Summary:

C1 - Single lymph node candidate, bisected
C2-C3 - Single lymph node candidate, serially sectioned
C4-C6 - Single lymph node candidate, serially sectioned
C7-C8 - Fat

Specimen D is labeled "right BLN" and is an aggregate of 3.2 x 2.5 x 1.1 cm of yellow/tan soft tissue fragments.

Block Summary:

D1 - Five lymph node candidates
D2 - Four lymph node candidates
D3 - Single lymph node candidate, bisected
D4-D5 - Single lymph node candidate, serially sectioned
D6-D7 - Single lymph node candidate, serially sectioned
D8-D12 - Fat

Source: NCI Genomic Data Commons file 141e3d58-872f-4119-a89a-11a8336415a1 (TCGA-EX-A3L1.39B5AD4F-9206-4AE5-96EF-AC8E5B2B10E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).